Somatic mutation profile of cancer-model specimen HCM-CSHL-0668-C18-85A (3D Organoid, passage 8; aliquot HCM-CSHL-0668-C18-85A-01D-A85C-36), derived from the primary tumor of HCMI case HCM-CSHL-0668-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 48.4 years (17,670 days).
Specimen HCM-CSHL-0668-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6fd4d1d-c6d4-41ce-a50f-be7a0798377e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0668-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0668-C18-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b77ee76a-eaa0-4c7b-b171-9f6201bd20e9

The open-access MAF lists 93 somatic variants for this specimen: 68 protein-altering or splice-affecting, 20 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 20, Nonsense Mutation 8, Intron 4, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2804dup p.Y935* | Nonsense Mutation (INS) | VAF 95/335 reads (28%) | hotspot (GDC flag); catalogued as rs863225332, CI023287, CI991958, COSV57344655; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 254/553 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 260/262 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.2336G>A p.G779D | Missense Mutation (SNP) | VAF 318/818 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144752316, COSV59392923; called by muse, varscan2
- ACAP3 | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 284/597 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.052); catalogued as rs780846497; called by muse, varscan2
- ALPK2 | c.1262G>T p.G421V | Missense Mutation (SNP) | VAF 116/274 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs1420697349, COSV64490713; called by mutect2, varscan2
- ARFGEF3 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 308/479 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs951236569; called by muse, varscan2
- BRINP3 | c.379C>A p.L127I | Missense Mutation (SNP) | VAF 112/282 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100818418; called by muse, varscan2
- C10orf90 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 34/460 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.731); catalogued as rs759428907; called by muse, mutect2
- C12orf40 | c.1846C>G p.L616V | Missense Mutation (SNP) | VAF 208/457 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV61136441, COSV61137527, COSV61137794; called by muse, mutect2, varscan2
- C2CD3 | c.1769C>T p.S590L | Missense Mutation (SNP) | VAF 242/386 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1272448828; called by muse, varscan2
- CLK3 | c.655C>T p.R219W (on ENST00000395066 / NM_001130028.1; = p.R71W on NM_003992.4) | Missense Mutation (SNP) | VAF 477/479 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750421202, COSV61412219; called by muse, varscan2
- DNAH1 | c.11275C>T p.R3759C | Missense Mutation (SNP) | VAF 130/488 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs540632160, COSV56231768; called by muse, varscan2
- ERC2 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 141/472 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs374728276, COSV99888305; called by muse, mutect2, varscan2
- GPR85 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 162/680 reads (24%) | SIFT tolerated (0.92); PolyPhen benign (0.028); catalogued as rs756442417, COSV51782887; called by muse, varscan2
- HTR1B | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 352/551 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64052011; called by muse, varscan2
- IL18RAP | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 298/492 reads (61%) | catalogued as rs770129762, COSV51828680; called by muse, varscan2
- INSYN2A | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 378/426 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs538792856, COSV99727622; called by muse, mutect2, varscan2
- KCNQ5 | c.2111C>T p.A704V | Missense Mutation (SNP) | VAF 177/583 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs776285517, COSV59652775; called by muse, varscan2
- KRTAP2-1 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 275/654 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.269); catalogued as rs1259905874; called by muse, varscan2
- LAMA4 | c.5345G>A p.R1782H (on ENST00000230538 / NM_001105206.3; = p.R1775H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 242/410 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs782638314; ClinVar: uncertain significance; called by muse, varscan2
- LHX8 | c.546G>T p.E182D | Missense Mutation (SNP) | VAF 132/280 reads (47%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.749); catalogued as COSV53956531; called by muse, varscan2
- MAGEA8 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 411/832 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs781942405; called by muse, varscan2
- MYBPC2 | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 177/263 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as rs756106442, COSV100732059; called by muse, mutect2, varscan2
- NRXN2 | c.4663G>A p.A1555T | Missense Mutation (SNP) | VAF 620/1063 reads (58%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.139); catalogued as rs746867181; called by muse, varscan2
- OSBPL2 | c.938C>T p.S313L (on ENST00000313733 / NM_144498.4; = p.S301L on NM_014835.4) | Missense Mutation (SNP) | VAF 234/605 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs757263045, COSV100569356; called by muse, mutect2, varscan2
- PCDHA7 | c.1697T>A p.L566Q | Missense Mutation (SNP) | VAF 46/982 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV100971287; called by muse, mutect2
- PLEC | c.7924C>T p.R2642W (on ENST00000322810 / NM_201380.4; = p.R2532W on NM_000445.5) | Missense Mutation (SNP) | VAF 405/827 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as rs782284017, COSV59683560; called by muse, varscan2
- RFWD3 | c.2066C>T p.T689I | Missense Mutation (SNP) | VAF 166/526 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1046069252; called by muse, mutect2, varscan2
- RNASE9 | c.150A>T p.K50N | Missense Mutation (SNP) | VAF 294/328 reads (90%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs774850516, COSV58880600; called by muse, mutect2, varscan2
- SCN5A | c.5435C>T p.S1812L (on ENST00000333535 / NM_198056.3; = p.S1811L on NM_000335.5) | Missense Mutation (SNP) | VAF 124/446 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs371891414, CM031356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCD3 | c.983G>A p.R328H (on ENST00000262188 / NM_001003801.2; = p.R315H on NM_003078.4) | Missense Mutation (SNP) | VAF 544/888 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs754353068, COSV50400462; called by muse, mutect2, varscan2
- SNAP91 | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 132/378 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as COSV104388092; called by muse, mutect2, varscan2
- SUPT16H | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 208/210 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53525999; called by muse, mutect2, varscan2
- TBXA2R | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 273/782 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs199924767; called by muse, varscan2
- TFEB | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 587/934 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs775220771, COSV57824723; called by muse, mutect2, varscan2
- TMEM132D | c.2092G>T p.E698* | Nonsense Mutation (SNP) | VAF 210/434 reads (48%) | catalogued as COSV101242741; called by muse, mutect2, varscan2
- TPTE | c.580C>T p.L194F (on ENST00000618007 / NM_199261.4; = p.L176F on NM_199259.4) | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.031); catalogued as rs776502829; called by muse, varscan2
- ZNF319 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 179/749 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1379127725; called by muse, varscan2
- ZNF549 | c.1384C>T p.R462* (on ENST00000376233 / NM_001199295.2; = p.R449* on NM_153263.2) | Nonsense Mutation (SNP) | VAF 137/478 reads (29%) | catalogued as rs375456560; called by muse, mutect2, varscan2
- ADAMTS5 | c.519G>A p.W173* | Nonsense Mutation (SNP) | VAF 220/982 reads (22%) | called by muse, varscan2
- DPH7 | c.877T>C p.F293L | Missense Mutation (SNP) | VAF 232/680 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, varscan2
- ERBB4 | c.2569G>A p.V857M | Missense Mutation (SNP) | VAF 309/511 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, varscan2
- GALNT17 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 560/912 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.409); called by muse, varscan2
- GRID2 | c.1402C>A p.Q468K | Missense Mutation (SNP) | VAF 178/190 reads (94%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- GRM5 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 140/407 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GTPBP2 | c.1276G>T p.V426F | Missense Mutation (SNP) | VAF 108/425 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- HDAC11 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 111/404 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HMCN1 | c.2896G>A p.A966T | Missense Mutation (SNP) | VAF 126/290 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- HMMR | c.564_571del p.Q188Hfs*35 | Frame Shift Del (DEL) | VAF 68/292 reads (23%) | called by mutect2, varscan2
- IRX5 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 402/629 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); called by muse, varscan2
- MAN2C1 | c.449G>A p.C150Y | Missense Mutation (SNP) | VAF 62/309 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MAP3K19 | c.2434G>T p.E812* | Nonsense Mutation (SNP) | VAF 141/517 reads (27%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.877A>G p.R293G | Missense Mutation (SNP) | VAF 182/626 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- MUC16 | c.15738C>A p.D5246E | Missense Mutation (SNP) | VAF 282/454 reads (62%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.38); called by mutect2, varscan2
- MYO16 | c.2719T>A p.Y907N | Missense Mutation (SNP) | VAF 226/363 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- MYO3A | c.3733A>C p.T1245P | Missense Mutation (SNP) | VAF 278/308 reads (90%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.047); called by muse, mutect2
- NETO2 | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 286/458 reads (62%) | called by muse, varscan2
- PFKFB3 | c.539C>A p.S180* | Nonsense Mutation (SNP) | VAF 243/276 reads (88%) | called by muse, mutect2, varscan2
- PHF3 | c.1145del p.G382Vfs*40 | Frame Shift Del (DEL) | VAF 56/361 reads (16%) | called by mutect2, varscan2
- PPRC1 | c.2293G>A p.A765T | Missense Mutation (SNP) | VAF 14/416 reads (3%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2
- SOGA1 | c.4484T>C p.L1495P | Missense Mutation (SNP) | VAF 508/1042 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TANC1 | c.4516A>G p.S1506G | Missense Mutation (SNP) | VAF 231/654 reads (35%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNFRSF1B | c.172T>A p.S58T | Missense Mutation (SNP) | VAF 112/278 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, varscan2
- UGT2B10 | c.789T>G p.F263L | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.028); called by muse, mutect2
- USP28 | c.2269T>C p.Y757H | Missense Mutation (SNP) | VAF 152/418 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ZNF529 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 271/454 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZNF90 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 223/347 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- C1orf52 | c.24T>G p.P8= | Silent (SNP) | VAF 164/326 reads (50%) | catalogued as rs749601140; called by muse, mutect2, varscan2
- CD276 | c.1443G>A p.L481= (on ENST00000318443 / NM_001024736.2; = p.L263= on NM_025240.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 440/442 reads (100%) | called by muse, mutect2, varscan2
- CFAP74 | c.2967C>T p.A989= | Silent (SNP) | VAF 198/396 reads (50%) | catalogued as rs1432650601; called by muse, mutect2, varscan2
- DHX34 | c.1737G>A p.L579= | Silent (SNP) | VAF 172/572 reads (30%) | catalogued as rs765990751; called by muse, varscan2
- GPR87 | c.289C>A p.R97= | Silent (SNP) | VAF 273/442 reads (62%) | catalogued as COSV53462939; called by muse, varscan2
- MAGEB2 | c.348G>A p.G116= | Silent (SNP) | VAF 437/1002 reads (44%) | called by muse, varscan2
- MIP | c.477C>T p.S159= | Silent (SNP) | VAF 339/754 reads (45%) | catalogued as rs201317497; called by muse, mutect2, varscan2
- MLLT6 | c.1602T>C p.P534= | Silent (SNP) | VAF 142/501 reads (28%) | called by muse, mutect2, varscan2
- OBSCN | c.13368C>T p.S4456= | Silent (SNP) | VAF 248/614 reads (40%) | catalogued as rs1231231846, COSV52741685; called by muse, varscan2
- PCIF1 | c.363C>T p.S121= | Silent (SNP) | VAF 231/528 reads (44%) | catalogued as rs1333820711, COSV100975959; called by muse, mutect2, varscan2
- POSTN | c.2253A>G p.E751= | Silent (SNP) | VAF 66/314 reads (21%) | called by muse, mutect2, varscan2
- POU4F3 | c.627C>T p.G209= | Silent (SNP) | VAF 370/599 reads (62%) | called by muse, mutect2, varscan2
- PPP5C | c.741C>T p.F247= | Silent (SNP) | VAF 265/465 reads (57%) | catalogued as rs762149325, COSV50139263; called by muse, mutect2, varscan2
- SDK1 | c.1086C>T p.C362= | Silent (SNP) | VAF 430/1170 reads (37%) | catalogued as rs752214798, COSV101269708, COSV67388623; called by muse, varscan2
- SYNPR | c.54C>T p.C18= | Silent (SNP) | VAF 235/369 reads (64%) | catalogued as rs758510661; called by muse, varscan2
- TCEANC | c.999C>T p.Y333= (on ENST00000380600 / NM_001297563.2; = p.Y363= on NM_152634.4) | Silent (SNP) | VAF 372/839 reads (44%) | catalogued as rs370372330, COSV59039826; called by muse, mutect2, varscan2
- TEX45 | c.12C>T p.G4= | Silent (SNP) | VAF 368/624 reads (59%) | called by muse, varscan2
- TRMT61A | c.834C>T p.T278= | Silent (SNP) | VAF 472/473 reads (100%) | catalogued as rs750457089; called by muse, mutect2, varscan2
- WASHC4 | c.2259G>A p.E753= | Silent (SNP) | VAF 201/482 reads (42%) | called by muse, mutect2, varscan2
- WDR44 | c.1761C>T p.D587= | Silent (SNP) | VAF 292/643 reads (45%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+2193T>A | Intron (SNP) | VAF 259/1304 reads (20%) | called by muse, varscan2
- CCDC140 | n.556C>A | RNA (SNP) | VAF 428/682 reads (63%) | catalogued as rs545278450, COSV54674749; called by muse, varscan2
- DPF3 | c.871+3023C>T | Intron (SNP) | VAF 355/359 reads (99%) | catalogued as rs751189350, COSV63503241; called by muse, mutect2, varscan2
- LAMA4 | c.195+28G>T | Intron (SNP) | VAF 432/680 reads (64%) | called by muse, mutect2, varscan2
- NHSL2 | c.-206-1258C>T | Intron (SNP) | VAF 284/673 reads (42%) | catalogued as rs1419116639, COSV65453180; called by muse, mutect2, varscan2
